Somatic mutation profile of tumor specimen MMRF_2635_1_BM_CD138pos (aliquot MMRF_2635_1_BM_CD138pos_T1_KHS5U_L13308) from MMRF case MMRF_2635, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.7 years (23,281 days).
Specimen MMRF_2635_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4b4aa7f6-947e-40cf-bdf1-896f95ea6952.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2635_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2635_1_PB_WBC_C3_KHS5U_L13309; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7635407f-e8f3-4f06-9865-e86204f4a1ef

The open-access MAF lists 76 somatic variants for this specimen: 24 protein-altering or splice-affecting, 9 silent, 43 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 25, Missense Mutation 19, Silent 9, Intron 9, 5'UTR 4, Frame Shift Del 3, 3'Flank 3, Nonsense Mutation 1, In Frame Del 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CCDC175 | c.1403G>A p.R468H | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.301); catalogued as rs527522644, COSV55790902; called by muse, mutect2, varscan2
- GRIA4 | c.1940C>T p.T647M | Missense Mutation (SNP) | VAF 82/242 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1439286427, COSV56887547; called by muse, mutect2, varscan2
- IGHV2-70 | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.072); catalogued as rs369066675; called by muse, varscan2
- IGKJ4 | c.22A>T p.K8* | Nonsense Mutation (SNP) | VAF 15/82 reads (18%) | catalogued as rs377458507; called by muse, mutect2, varscan2
- IGKV4-1 | c.355A>C p.S119R | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as rs765595032; called by muse, mutect2, varscan2
- MCHR2 | c.623del p.F208Sfs*5 | Frame Shift Del (DEL) | VAF 10/56 reads (18%) | catalogued as rs759525627, COSV55999002; called by mutect2, varscan2
- PANX2 | c.646C>T p.R216C | Missense Mutation (SNP) | VAF 46/264 reads (17%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); catalogued as rs547616581, COSV50303152; called by muse, mutect2, varscan2
- SOCS6 | c.805G>A p.V269I | Missense Mutation (SNP) | VAF 72/437 reads (16%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0); catalogued as rs770332863, COSV67546296; called by muse, mutect2, varscan2
- CACNA1D | c.3648G>C p.M1216I (on ENST00000350061 / NM_001128840.3; = p.M1236I on NM_000720.4) | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2
- CD36 | c.252A>C p.Q84H | Missense Mutation (SNP) | VAF 183/577 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- COL1A2 | c.2417C>T p.P806L | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- IGDCC4 | c.3057G>T p.E1019D | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- IGKV3-20 | c.23T>C p.L8P | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.822); called by muse, mutect2, varscan2
- LGI3 | c.401G>A p.G134E | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRC10B | c.184_186del p.E62del | In Frame Del (DEL) | VAF 12/58 reads (21%) | called by pindel, varscan2
- MAGI2 | c.505A>G p.S169G | Missense Mutation (SNP) | VAF 29/149 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- OR5F1 | c.402G>C p.L134F | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- PLA2G4A | c.1005A>C p.K335N | Missense Mutation (SNP) | VAF 37/179 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PTPRA | c.599del p.V200Gfs*73 | Frame Shift Del (DEL) | VAF 19/106 reads (18%) | called by mutect2, pindel, varscan2
- RBBP8 | c.823_832del p.M275Lfs*29 | Frame Shift Del (DEL) | VAF 33/284 reads (12%) | called by mutect2, pindel, varscan2
- RXFP3 | c.43G>T p.A15S | Missense Mutation (SNP) | VAF 31/398 reads (8%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.045); called by muse, mutect2
- SEMA5B | c.2458G>A p.E820K | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- SERPINB10 | c.974T>A p.M325K | Missense Mutation (SNP) | VAF 54/280 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- COL8A1 | c.1944G>A p.P648= | Silent (SNP) | VAF 33/158 reads (21%) | catalogued as rs1354318040, COSV53732736; called by muse, mutect2, varscan2
- F13A1 | c.405T>C p.I135= | Silent (SNP) | VAF 24/126 reads (19%) | called by muse, mutect2, varscan2
- FLT4 | c.546G>A p.E182= | Silent (SNP) | VAF 20/120 reads (17%) | catalogued as rs1325897547; called by muse, mutect2, varscan2
- GJA9 | c.1389A>G p.Q463= | Silent (SNP) | VAF 42/159 reads (26%) | called by muse, mutect2, varscan2
- IGHV2-70 | c.96A>G p.K32= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as rs368957766; called by muse, varscan2
- PRSS1 | c.472C>T p.L158= | Silent (SNP) | VAF 56/259 reads (22%) | catalogued as rs1563262178; called by muse, mutect2, varscan2
- SLC6A5 | c.2175C>T p.S725= | Silent (SNP) | VAF 12/99 reads (12%) | catalogued as rs766853243, COSV54228958; called by mutect2, varscan2
- SMAD6 | c.1140G>A p.V380= | Silent (SNP) | VAF 60/377 reads (16%) | called by muse, mutect2, varscan2
- SPTBN4 | c.3849G>A p.L1283= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as rs913428718; called by muse, mutect2, varscan2
- AC005324.2 | c.*122T>G | 3'UTR (SNP) | VAF 44/214 reads (21%) | called by muse, mutect2, varscan2
- ACER2 | c.*855G>A | 3'UTR (SNP) | VAF 12/261 reads (5%) | called by muse, mutect2
- ADAMTS17 | c.*1947C>A | 3'UTR (SNP) | VAF 31/144 reads (22%) | catalogued as rs558565090; called by muse, mutect2, varscan2
- ARL8B | c.*48T>G | 3'UTR (SNP) | VAF 208/574 reads (36%) | called by muse, mutect2, varscan2
- BMP6 | c.*1144_*1184del | 3'UTR (DEL) | VAF 14/80 reads (18%) | called by mutect2, pindel
- CD47 | c.*2071A>G | 3'UTR (SNP) | VAF 10/51 reads (20%) | catalogued as rs1431873023, COSV100790107; called by muse, mutect2, varscan2
- CDH5 | c.*962C>A | 3'UTR (SNP) | VAF 53/226 reads (23%) | catalogued as COSV58517135; called by muse, mutect2, varscan2
- CENATAC | chr11:119018652 del GCAGGTGGCTGCAC | 3'Flank (DEL) | VAF 21/108 reads (19%) | called by mutect2, pindel, varscan2
- CLEC16A | c.-57C>T | 5'UTR (SNP) | VAF 13/61 reads (21%) | called by muse, mutect2, varscan2
- EPHA10 | c.-33C>T | 5'UTR (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
- FAM135A | c.*891A>C | 3'UTR (SNP) | VAF 6/32 reads (19%) | called by muse, mutect2, varscan2
- FAU | c.220+119_220+123del | Intron (DEL) | VAF 31/110 reads (28%) | called by pindel, varscan2
- GPM6A | c.37+24740C>T | Intron (SNP) | VAF 34/195 reads (17%) | catalogued as rs779191380; called by muse, mutect2, varscan2
- IGF2 | chr11:2129779 C>A | 3'Flank (SNP) | VAF 23/109 reads (21%) | called by muse, mutect2, varscan2
- IGHJ6 | chr14:105863420 C>G | 5'Flank (SNP) | VAF 5/17 reads (29%) | called by muse, varscan2
- KCNJ15 | c.*1273T>A | 3'UTR (SNP) | VAF 15/63 reads (24%) | called by muse, mutect2, varscan2
- KIF1B | c.*3351C>T | 3'UTR (SNP) | VAF 12/77 reads (16%) | catalogued as rs910775676; called by muse, mutect2, varscan2
- LINC01257 | n.543G>A | RNA (SNP) | VAF 4/14 reads (29%) | called by mutect2, varscan2
- LMAN1L | chr15:74825844 G>A | 3'Flank (SNP) | VAF 19/133 reads (14%) | catalogued as rs1269766354; called by muse, mutect2, varscan2
- MYO15A | c.9304-65T>G | Intron (SNP) | VAF 69/379 reads (18%) | called by muse, mutect2, varscan2
- NOX4 | c.57+256C>G | Intron (SNP) | VAF 38/251 reads (15%) | called by muse, mutect2, varscan2
- PALB2 | c.-88C>T | 5'UTR (SNP) | VAF 11/58 reads (19%) | catalogued as rs1471091819; called by muse, mutect2, varscan2
- PDE3A | c.*3797T>A | 3'UTR (SNP) | VAF 9/30 reads (30%) | called by muse, mutect2, varscan2
- PLXNC1 | c.*101T>C | 3'UTR (SNP) | VAF 74/340 reads (22%) | called by muse, mutect2, varscan2
- RAG1 | c.*634C>A | 3'UTR (SNP) | VAF 17/78 reads (22%) | called by muse, mutect2, varscan2
- RSPO2 | c.-17C>A | 5'UTR (SNP) | VAF 36/145 reads (25%) | catalogued as COSV99410427; called by muse, mutect2, varscan2
- SERP1 | c.*337A>G | 3'UTR (SNP) | VAF 14/79 reads (18%) | called by muse, mutect2, varscan2
- SHH | c.*1056C>T | 3'UTR (SNP) | VAF 6/43 reads (14%) | catalogued as rs565394086; called by muse, mutect2, varscan2
- SLC2A3 | c.*480T>C | 3'UTR (SNP) | VAF 13/118 reads (11%) | called by muse, mutect2, varscan2
- SPATA16 | c.*68C>T | 3'UTR (SNP) | VAF 8/58 reads (14%) | called by muse, mutect2, varscan2
- SUGP2 | c.3128+217G>T | Intron (SNP) | VAF 18/83 reads (22%) | called by muse, mutect2, varscan2
- TCTN1 | c.473-644T>G | Intron (SNP) | VAF 72/320 reads (23%) | called by muse, varscan2
- TCTN1 | c.473-547T>C | Intron (SNP) | VAF 26/136 reads (19%) | called by muse, varscan2
- TNKS1BP1 | c.*336T>G | 3'UTR (SNP) | VAF 6/42 reads (14%) | called by muse, mutect2
- TNXB | c.11347+333C>T | Intron (SNP) | VAF 41/198 reads (21%) | called by muse, mutect2, varscan2
- TXLNG | c.*558A>G | 3'UTR (SNP) | VAF 20/53 reads (38%) | called by muse, mutect2, varscan2
- UBL5 | c.178+24G>A | Intron (SNP) | VAF 111/307 reads (36%) | called by muse, mutect2, varscan2
- UGT8 | c.*1357G>T | 3'UTR (SNP) | VAF 15/67 reads (22%) | called by muse, mutect2, varscan2
- UMAD1 | c.*1222A>C | 3'UTR (SNP) | VAF 18/137 reads (13%) | called by muse, mutect2, varscan2
- VAMP4 | c.*2741T>G | 3'UTR (SNP) | VAF 23/77 reads (30%) | called by muse, mutect2, varscan2
- VCL | c.*1677A>G | 3'UTR (SNP) | VAF 16/79 reads (20%) | catalogued as rs1401369101; called by muse, mutect2, varscan2
- WDR47 | c.*987G>A | 3'UTR (SNP) | VAF 11/67 reads (16%) | called by muse, mutect2, varscan2
- ZSCAN5A | c.*92C>T | 3'UTR (SNP) | VAF 20/105 reads (19%) | catalogued as rs1019389882; called by muse, mutect2, varscan2
